Somatic mutation profile of tumor specimen TCGA-AM-5820-01A (aliquot TCGA-AM-5820-01A-01D-1650-10) from TCGA case TCGA-AM-5820, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVA; Age at diagnosis: 60.0 years (21,902 days).
Specimen TCGA-AM-5820-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22e232e7-9f63-4ccf-946a-ebe9796fe3cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AM-5820-10A (Blood Derived Normal), aliquot TCGA-AM-5820-10A-01D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/832b89e0-c43a-4a02-b44c-bb905d08f2ff

The open-access MAF lists 68 somatic variants for this specimen: 52 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 49, Silent 16, Frame Shift Del 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABL2 | c.1952G>A p.G651D (on ENST00000502732 / NM_007314.4; = p.G636D on NM_005158.5) | Missense Mutation (SNP) | VAF 65/148 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.546); catalogued as COSV61012366, COSV61021327; called by muse, mutect2, varscan2
- ARHGAP15 | c.80G>C p.R27T | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV54501633, COSV54509102, COSV54524799; called by muse, mutect2, varscan2
- CDH18 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 101/238 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.401); catalogued as rs148450624, COSV56937399; called by muse, mutect2, varscan2
- CDO1 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.019); catalogued as rs776077445, COSV51664332; called by muse, mutect2, varscan2
- CHEK2 | c.1322C>G p.S441C (on ENST00000382580 / NM_001005735.2; = p.S398C on NM_007194.4) | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV60419464; called by muse, mutect2, varscan2
- COL28A1 | c.2221C>T p.R741W | Missense Mutation (SNP) | VAF 191/360 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.72); catalogued as rs201020782, COSV68083728; called by muse, varscan2
- CSMD1 | c.5903C>T p.S1968F (on ENST00000520002; = p.S1967F on NM_033225.6) | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.998); catalogued as COSV59392618; called by muse, mutect2, varscan2
- DCHS1 | c.4768G>A p.G1590S | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs934539374, COSV55033450; called by muse, mutect2, varscan2
- DNAH8 | c.3959G>A p.R1320H | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.597); catalogued as rs375507271; ClinVar: uncertain significance; called by muse, varscan2
- DPF2 | c.857C>T p.T286M | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs1194823894, COSV52889581; called by muse, varscan2
- EGR2 | c.535G>A p.G179R | Missense Mutation (SNP) | VAF 91/210 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1314006597, COSV104386904, COSV54349139; called by muse, mutect2, varscan2
- ERLIN2 | c.395C>T p.T132M | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs772986050, COSV52422215; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FGF5 | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.048); catalogued as COSV56890241, COSV56892223; called by muse, varscan2
- FNDC11 | c.779T>C p.V260A | Missense Mutation (SNP) | VAF 46/79 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100918810; called by muse, varscan2
- FOXG1 | c.724G>A p.V242M | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV57399961; called by muse, varscan2
- GPLD1 | c.1498C>T p.P500S | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100015067, COSV57761601; called by muse, mutect2, varscan2
- GTF2H1 | c.1490T>C p.L497S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.351); catalogued as COSV99786512; called by muse, mutect2, varscan2
- HIPK3 | c.224A>G p.N75S | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV57561625; called by muse, mutect2, varscan2
- KCNH2 | c.3280C>A p.L1094M | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.496); catalogued as rs772691915, COSV51235508; called by muse, mutect2, varscan2
- KCTD18 | c.995C>T p.T332M | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.027); catalogued as rs199722039, COSV63345232; called by muse, mutect2, varscan2
- KMT2B | c.4949C>T p.T1650M | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555731828, COSV55860020; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMA2 | c.7612G>C p.E2538Q | Missense Mutation (SNP) | VAF 52/87 reads (60%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV70356258; called by muse, mutect2, varscan2
- LAMA5 | c.7579C>T p.R2527C | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.2); catalogued as rs756250563, COSV53373929; called by muse, mutect2, varscan2
- LILRA4 | c.700G>A p.V234M | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.402); catalogued as rs763023157, COSV52493499; called by muse, varscan2
- LRIT3 | c.1052C>T p.T351I | Missense Mutation (SNP) | VAF 78/195 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV59987960; called by muse, mutect2, varscan2
- MDM1 | c.230A>T p.E77V | Missense Mutation (SNP) | VAF 120/355 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.892); catalogued as COSV57449147; called by muse, varscan2
- MYO16 | c.2994G>T p.K998N | Missense Mutation (SNP) | VAF 85/215 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62755148, COSV62763442; called by muse, mutect2, varscan2
- NR2F6 | c.149C>A p.P50Q | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV52245761; called by mutect2, varscan2
- OR14A16 | c.652C>T p.H218Y | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.017); catalogued as COSV100713806; called by muse, varscan2
- OR2Y1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as rs776793152, COSV57136597; called by muse, mutect2, varscan2
- PTPRZ1 | c.710C>A p.S237Y | Missense Mutation (SNP) | VAF 68/144 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV66436699; called by muse, varscan2
- QPCTL | c.533C>T p.S178L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs750481449, COSV50003821; called by mutect2, varscan2
- RANBP9 | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50586624; called by muse, varscan2
- ROBO1 | c.1466G>T p.R489I | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.193); catalogued as COSV71394408, COSV71394574; called by muse, mutect2, varscan2
- SEMA5B | c.2657G>A p.R886H | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); catalogued as rs746855310, COSV52109459; called by muse, varscan2
- SESN3 | c.816del p.Q273Kfs*14 | Frame Shift Del (DEL) | VAF 82/254 reads (32%) | catalogued as rs1471574508; called by mutect2, pindel, varscan2
- SETDB1 | c.1843C>T p.R615C | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1417753952, COSV99645044; called by muse, mutect2, varscan2
- SLC2A14 | c.179C>A p.T60K | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs190134197, COSV61588852; called by muse, varscan2
- SNAI3 | c.374C>T p.S125F | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV60003535; called by muse, mutect2, varscan2
- SPANXN3 | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 90/256 reads (35%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.925); catalogued as COSV65140886; called by muse, mutect2, varscan2
- SPEG | c.3017G>A p.R1006H | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs571127512; called by muse, mutect2, varscan2
- SPNS3 | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs778200264, COSV61070193; called by muse, mutect2, varscan2
- SPON1 | c.325G>C p.D109H | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.726); catalogued as COSV100116142; called by muse, mutect2, varscan2
- TENM2 | c.6922C>T p.R2308W (on ENST00000518659 / NM_001122679.2; = p.R2069W on NM_001080428.3) | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371902949; called by muse, mutect2, varscan2
- TFPI2 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs543669576, COSV55990653; called by muse, mutect2, varscan2
- TTN | c.50428C>T p.R16810* (on ENST00000591111; = p.R9386* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 76/197 reads (39%) | catalogued as rs1440093502, COSV60105753; called by muse, mutect2, varscan2
- XKR7 | c.1474C>T p.R492C | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs779419531, COSV73813506; called by muse, mutect2, varscan2
- ZBTB20 | c.919G>A p.E307K (on ENST00000474710 / NM_001164342.2; = p.E234K on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV100614187; called by muse, mutect2, varscan2
- ZNF217 | c.2969A>G p.Y990C | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as rs371730112; called by mutect2, varscan2
- ZNF33A | c.1169G>C p.G390A (on ENST00000458705 / NM_006974.3; = p.G391A on NM_006954.2) | Missense Mutation (SNP) | VAF 15/167 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.079); catalogued as COSV100275415, COSV100275944; called by muse, mutect2, varscan2
- ZNF551 | c.65T>A p.L22Q | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.094); catalogued as COSV56595435; called by muse, mutect2, varscan2
- BCL9 | c.3330del p.P1111Lfs*3 | Frame Shift Del (DEL) | VAF 34/92 reads (37%) | called by mutect2, varscan2
- ABCC4 | c.1773T>G p.T591= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV100972575; called by muse, mutect2, varscan2
- ADGRB1 | c.4077C>A p.P1359= | Silent (SNP) | VAF 36/85 reads (42%) | catalogued as COSV100029832; called by muse, mutect2, varscan2
- AMIGO2 | c.1131C>T p.D377= | Silent (SNP) | VAF 34/81 reads (42%) | catalogued as rs774547090, COSV99873666; called by muse, mutect2, varscan2
- ARHGEF26 | c.594C>T p.P198= | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as rs894989795, COSV100726690, COSV62846517; called by muse, mutect2, varscan2
- CCDC130 | c.912G>A p.P304= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs1292157362, COSV99237580; called by muse, mutect2, varscan2
- CELSR3 | c.4197C>T p.S1399= | Silent (SNP) | VAF 68/103 reads (66%) | catalogued as rs373483249, COSV51167470; called by muse, varscan2
- DNAI1 | c.1599C>T p.L533= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as rs150785761, COSV54284353; called by muse, mutect2, varscan2
- FRMPD4 | c.2538C>T p.P846= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as rs751438887, COSV66224466; called by muse, mutect2, varscan2
- MUC17 | c.7149C>T p.D2383= | Silent (SNP) | VAF 64/249 reads (26%) | catalogued as rs138267850, COSV100075844, COSV60305969; called by muse, varscan2
- NYNRIN | c.498G>T p.L166= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV101230628; called by muse, mutect2
- RPN2 | c.588C>T p.G196= | Silent (SNP) | VAF 24/112 reads (21%) | catalogued as rs370536029; called by muse, varscan2
- SLC14A2 | c.1725C>T p.S575= | Silent (SNP) | VAF 72/103 reads (70%) | catalogued as COSV54915155; called by muse, varscan2
- TNFAIP6 | c.792T>A p.T264= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as COSV99693940; called by muse, mutect2, varscan2
- USP34 | c.627G>A p.L209= | Silent (SNP) | VAF 9/108 reads (8%) | catalogued as COSV68400667; called by muse, mutect2
- VSTM2A | c.144C>T p.C48= | Silent (SNP) | VAF 38/123 reads (31%) | catalogued as rs764137275, COSV56494205; called by muse, mutect2, varscan2
- ZNF536 | c.2064G>A p.T688= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV62821150; called by muse, mutect2, varscan2
